Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040028-04A.3 (aliquot TARGET-15-SJMPAL040028-04A.3-01D) from TARGET case TARGET-15-SJMPAL040028, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.2 years (6,265 days).
Specimen TARGET-15-SJMPAL040028-04A.3: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e13d52e-54da-4a1b-b5e6-234c48dff032.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040028-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040028-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c5ab1fe-ce96-420f-818a-9baaed35cfbe

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Ins 1, Splice Region 1, 5'UTR 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15210T>A p.Y5070* | Nonsense Mutation (SNP) | VAF 40/84 reads (48%) | catalogued as COSV56491819; called by muse, mutect2, varscan2
- MYCN | c.134dup p.E47Gfs*8 | Frame Shift Ins (INS) | VAF 26/76 reads (34%) | catalogued as rs780080562; called by mutect2, varscan2
- ZNF608 | c.2207G>A p.R736Q | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200298192, COSV60437581; called by muse, mutect2, varscan2
- DNAH17 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- EML5 | c.1933G>T p.V645F | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FBXL18 | c.1180C>T p.H394Y | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MSC | c.226C>G p.R76G | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEU1 | c.1021+4_1021+7del | Splice Region (DEL) | VAF 85/190 reads (45%) | called by mutect2, varscan2
- RNF11 | c.314A>G p.D105G | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SMARCA4 | c.1684G>C p.A562P | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.885); called by muse, varscan2
- EFTUD2 | c.1212G>A p.T404= | Silent (SNP) | VAF 54/92 reads (59%) | catalogued as rs200389815; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP1R26 | c.1509C>T p.D503= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs377344013; called by muse, mutect2
- ITFG2 | c.406+9G>T | Intron (SNP) | VAF 70/141 reads (50%) | catalogued as COSV57390913; called by muse, varscan2
- NPC1L1 | c.-6_-5insT | 5'UTR (INS) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
